Surgical pathology report (de-identified scan), TCGA case TCGA-B8-5164, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-5164-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Diagnosis:

Kidney, right, right hand assisted laparoscopic nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, clear cell type

Histologic grade (if applicable): Fuhrman grade 3 of 4

Tumor size (greatest dimension): 5.2 cm

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: tumor invades into capsule; perirenal (capsular) adipose tissue negative for malignancy

Gerota's fascia: negative for malignancy

Renal vein: negative for malignancy

Ureter: negative for malignancy

Venous (large vessel): positive for carcinoma (A11)

Lymphatic (small vessel): positive for carcinoma (A2)

Histologic assessment of surgical margins:

Perirenal adipose tissue: negative for malignancy

Gerota's fascia: negative for malignancy

Renal vein: negative for malignancy

Renal artery: negative for malignancy

Ureter: negative for malignancy

Other significant findings:

- Mild arterial sclerosis.

- Tumor extends into perihilar fat (A11).

AJCC Staging:

pT3a

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

The patient is with a clinical diagnosis of a right kidney mass. As per, radiology shows an enhancing mass in the inferior pole.

Gross Description:

Received is one appropriately labeled container, additionally labeled "right kidney".

Specimen fixation: Formalin

Type of specimen: Laparoscopic

Side of specimen: Right

Size and weight of specimen: 750 grams; 22.0 x 13.0 x 8.0 cm over all, kidney is 12.0 x 8.0 x 7.0 cm; the adrenal gland is not present.

[page 2 of 2]
Orientation: The specimen has been received previously inked blue, which = perirenal fat.

Presence/absence of adrenal gland: Absent

Tumor description/site: Anatomic site: renal cortex; lower pole; the tumor appears yellow to dark brown in color, with variation across the entire greatest dimension. Focal necrosis is evident. The tumor is encapsulated.

Tumor size: 5.3 x 5.0 x 4.6 cm

Presence/absence of multicentricity: Absent

Confinement/non-confinement to the kidney: Confined

Extent of invasion:

Perirenal adipose tissue: Negative

Gerota's fascia: Negative

Renal vein: Negative

Ureter: Negative

Other organs: N/A

Surgical margins:

Perirenal adipose tissue: Negative, 1.0 cm away at closest approach

Renal vein: Negative, 2.0 cm away at closest approach

Renal artery: Negative, 2.0 cm away at closest approach

Ureter: Negative, 0.7 cm away at closest approach

Description of kidney away from tumor: Tan/brown in color with cortex measuring 0.6 cm and the average medullary space measuring 0.7 cm. No other lesions or masses are noted.

Lymph nodes (hilar): N/A

Other significant findings: No

Tissue submitted for special investigations: Yes

Digital photograph taken: No

Block Summary:

Inking: Blue/perirenal fat

A1 - Ureter, vein, artery margin

A2 - Tumor with inked perirenal fat, closest approach

A3 - Tumor with transition into normal parenchyma

A4-A8 - Tumor with capsule

A9 - Central tumor

A10 - Tumor and urothelium

A11 - Hilum, perpendicular section

A12 - Normal kidney and urothelium

Grossing Pathologist:

Light Microscopy:

Light microscopic examination is performed

[REDACTED]

Source: NCI Genomic Data Commons file 768c1387-2343-479b-97f2-ab6fb93f39d8 (TCGA-B8-5164.E5FC86B5-71DA-4E10-A3B0-44C588723BB6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).